Somatic mutation profile of tumor specimen TCGA-22-A5C4-01A (aliquot TCGA-22-A5C4-01A-12D-A27K-08) from TCGA case TCGA-22-A5C4, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,629 days).
Specimen TCGA-22-A5C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52be1f8c-653d-4664-9152-3075fed62484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-22-A5C4-10A (Blood Derived Normal), aliquot TCGA-22-A5C4-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bd5c468-3766-4f46-a07c-5575720a2ea8

The open-access MAF lists 394 somatic variants for this specimen: 308 protein-altering or splice-affecting, 78 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 249, Silent 78, Frame Shift Del 22, Nonsense Mutation 20, Splice Site 10, Intron 5, Frame Shift Ins 3, 3'UTR 2, Splice Region 2, 5'Flank 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | hotspot (GDC flag); catalogued as rs121913387, CM940227, COSV58682666, COSV58721549, COSV99053472; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as COSV99226102; called by muse, mutect2, varscan2
- ACACB | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs763514954, COSV100622904; called by muse, mutect2, varscan2
- ADAM12 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 82/186 reads (44%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.815); catalogued as COSV100900537; called by muse, mutect2, varscan2
- ADAM9 | c.827G>T p.G276V | Missense Mutation (SNP) | VAF 30/233 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); catalogued as COSV101122258; called by muse, mutect2, varscan2
- ADCY5 | c.3613G>A p.V1205M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59202303; called by muse, mutect2, varscan2
- ADCYAP1 | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV99327524; called by muse, varscan2
- AKAP9 | c.5723_5726del p.T1908Sfs*2 (on ENST00000359028; = p.T1876Sfs*2 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 10/44 reads (23%) | catalogued as rs755378911; called by pindel, varscan2
- ALKBH5 | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99232814; called by muse, mutect2, varscan2
- ALS2 | c.1930A>G p.T644A | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV99969298; called by muse, mutect2, varscan2
- ANKMY2 | c.721A>T p.N241Y | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.423); catalogued as COSV100187092; called by muse, mutect2, varscan2
- AP3D1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1343599339, COSV100642681; called by muse, mutect2, varscan2
- ARID1B | c.4748C>G p.P1583R | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as COSV99034289, COSV99269161; called by muse, mutect2, varscan2
- ARMC3 | c.1355A>G p.N452S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.125); catalogued as COSV99958083; called by mutect2, varscan2
- ATG9A | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100772584; called by muse, mutect2, varscan2
- ATP10B | c.3139C>T p.R1047C | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs370681181; called by muse, mutect2, varscan2
- ATXN2L | c.1093C>G p.R365G | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV100294330, COSV57376322; called by muse, mutect2, varscan2
- BMP3 | c.707C>G p.P236R | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV99261681; called by muse, mutect2, varscan2
- BNC2 | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as rs1296819700, COSV101033244; called by muse, mutect2, varscan2
- BTNL2 | c.1121A>T p.D374V | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV100896089; called by muse, mutect2, varscan2
- CAPN13 | c.1088G>T p.G363V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.412); catalogued as COSV54429960, COSV99700242; called by muse, mutect2, varscan2
- CATSPER4 | c.90del p.F31Lfs*5 | Frame Shift Del (DEL) | VAF 28/51 reads (55%) | catalogued as COSV100128155; called by mutect2, pindel, varscan2
- CCDC39 | c.172C>A p.H58N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99868891; called by muse, mutect2, varscan2
- CCNY | c.402-1G>T p.X134_splice | Splice Site (SNP) | VAF 22/108 reads (20%) | catalogued as COSV99590591; called by muse, mutect2, varscan2
- CD163 | c.443G>C p.G148A | Missense Mutation (SNP) | VAF 44/266 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.475); catalogued as COSV100775839, COSV63131472; called by muse, mutect2, varscan2
- CD33 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV99220438; called by muse, mutect2, varscan2
- CDH10 | c.745T>A p.L249I | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100051465; called by muse, mutect2, varscan2
- CDH12 | c.1982A>G p.D661G | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101202530; called by muse, mutect2
- CDH20 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752821000, COSV53020851, COSV99405403; called by muse, mutect2, varscan2
- CDH8 | c.2311C>G p.Q771E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.967); catalogued as COSV100181544; called by muse, mutect2, varscan2
- CELA3B | c.77C>A p.S26Y | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.125); catalogued as COSV100448740, COSV61405330; called by muse, mutect2, varscan2
- CEP250 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.229); catalogued as rs1171819903, COSV100698931; called by muse, mutect2, varscan2
- CERT1 | c.919C>T p.Q307* (on ENST00000405807 / NM_001130105.1; = p.Q179* on NM_005713.3) | Nonsense Mutation (SNP) | VAF 42/66 reads (64%) | catalogued as COSV99783256; called by muse, mutect2, varscan2
- CFAP47 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV99935045; called by muse, varscan2
- CFAP77 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.087); catalogued as COSV100545829; called by muse, mutect2, varscan2
- CFTR | c.2295G>T p.R765S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136229; called by muse, mutect2, varscan2
- CGB5 | c.252C>G p.F84L | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100032025, COSV100032156; called by muse, mutect2, varscan2
- CLVS1 | c.456-2A>G p.X152_splice | Splice Site (SNP) | VAF 36/143 reads (25%) | catalogued as COSV57974962; called by muse, mutect2, varscan2
- COL22A1 | c.4348G>T p.G1450* | Nonsense Mutation (SNP) | VAF 33/136 reads (24%) | catalogued as COSV100278503; called by muse, mutect2, varscan2
- COL4A6 | c.3890C>G p.P1297R | Missense Mutation (SNP) | VAF 32/49 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100564110, COSV100564365; called by muse, mutect2, varscan2
- COL5A3 | c.4961C>T p.A1654V | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV99318913; called by muse, mutect2, varscan2
- CPA6 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99913601; called by muse, mutect2, varscan2
- CPS1 | c.3453C>G p.F1151L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.372); catalogued as COSV99243039; called by muse, mutect2, varscan2
- CPXM1 | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 89/166 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101013733; called by muse, mutect2, varscan2
- CR1 | c.2639G>T p.G880V | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100887610; called by muse, mutect2
- CRB1 | c.3960G>T p.Q1320H | Missense Mutation (SNP) | VAF 32/264 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.823); catalogued as COSV100957878; called by muse, mutect2, varscan2
- CRIM1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 46/239 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs965547947, COSV54860775; called by muse, mutect2, varscan2
- CSHL1 | c.306C>T p.S102= (on ENST00000309894 / NM_022581.3; = p.S8= on NM_001318.4) | Splice Region (SNP) | VAF 57/138 reads (41%) | catalogued as rs748460636, COSV99367985; called by muse, mutect2, varscan2
- CSMD3 | c.5372C>G p.S1791C (on ENST00000297405 / NM_001363185.1; = p.S1687C on NM_052900.3) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.926); catalogued as COSV99834440; called by muse, mutect2, varscan2
- CTNNA3 | c.1270A>T p.R424W | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101049293; called by muse, mutect2, varscan2
- CUBN | c.8731G>T p.G2911C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912681, COSV64714813; called by muse, mutect2, varscan2
- CUBN | c.5655T>A p.N1885K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV100912682; called by muse, mutect2, varscan2
- CUL9 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV99335219; called by muse, mutect2
- CYP11B2 | c.779G>T p.W260L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100011020; called by muse, mutect2, varscan2
- DAGLA | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99944383; called by muse, mutect2, varscan2
- DHTKD1 | c.224C>A p.P75H | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99536441; called by muse, mutect2, varscan2
- DIP2C | c.1844G>T p.R615L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as COSV55151569, COSV99791696; called by muse, mutect2, varscan2
- DKK1 | c.711T>A p.C237* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV64760374; called by muse, mutect2, varscan2
- DLEC1 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV100342378; called by muse, mutect2, varscan2
- DNAH10 | c.12071G>A p.R4024H (on ENST00000409039; = p.R3963H on NM_207437.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777448802, COSV101292257; called by muse, mutect2
- DNAJC13 | c.5038A>T p.S1680C | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV53456830, COSV99607279; called by muse, mutect2, varscan2
- DPF3 | c.561C>A p.D187E | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.537); catalogued as COSV100818571, COSV63499868; called by muse, mutect2, varscan2
- DPP4 | c.2201G>T p.W734L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV100858866; called by muse, mutect2, varscan2
- DPYS | c.1108G>T p.D370Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100037135; called by muse, mutect2, varscan2
- DPYS | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100679642, COSV60906475; called by muse, mutect2
- EFNB1 | c.467G>C p.R156P | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV52661059, COSV99214841; called by muse, mutect2, varscan2
- EML1 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1360737562, COSV99214835, COSV99215017; called by muse, mutect2, varscan2
- EML2 | c.511-2A>G p.X171_splice | Splice Site (SNP) | VAF 16/39 reads (41%) | catalogued as COSV99840028; called by muse, mutect2, varscan2
- ERICH1 | c.365A>T p.K122I | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV100032505; called by muse, mutect2, varscan2
- FAAH2 | c.1144G>T p.G382C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100887297; called by muse, mutect2, varscan2
- FABP3 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 107/373 reads (29%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.747); catalogued as COSV100703999; called by muse, mutect2, varscan2
- FAM120B | c.1642A>T p.T548S | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.466); catalogued as COSV99379383; called by muse, mutect2, varscan2
- FAM47A | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 146/167 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV60500128; called by muse, mutect2, varscan2
- FAP | c.2099C>T p.T700I | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99502173; called by muse, mutect2, varscan2
- FAR1 | c.1212G>C p.E404D | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100701575; called by muse, mutect2
- FASN | c.7069C>T p.P2357S | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as rs1210850990, COSV60755576; called by muse, mutect2, varscan2
- FASN | c.4649C>T p.S1550L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.215); catalogued as rs759056728, COSV100147801; called by muse, varscan2
- FAT4 | c.13900G>T p.D4634Y | Missense Mutation (SNP) | VAF 36/61 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100628629; called by muse, mutect2, varscan2
- FER1L6 | c.2256C>A p.H752Q | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.417); catalogued as COSV101205853; called by muse, mutect2, varscan2
- FGG | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV100271869; called by muse, mutect2, varscan2
- FHDC1 | c.2777G>T p.G926V | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV99471280; called by muse, mutect2, varscan2
- FHIT | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as COSV100534345; called by muse, mutect2
- FLNB | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.139); catalogued as rs781162510, COSV55873162, COSV99913235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.1337G>C p.R446P | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100145081, COSV60415433, COSV99070470; called by muse, mutect2, varscan2
- FNBP1 | c.1499A>T p.Y500F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100852688; called by muse, mutect2, varscan2
- FNDC7 | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 116/173 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV99601244; called by muse, mutect2, varscan2
- FRMPD3 | c.3941G>A p.R1314H | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs758378389, COSV99346333; called by muse, mutect2, varscan2
- FSCB | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV100469332, COSV61218576; called by muse, mutect2, varscan2
- FSCN3 | c.299A>C p.H100P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV50001841, COSV99133750, COSV99134020; called by muse, mutect2, varscan2
- FSHR | c.935C>T p.S312F | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.056); catalogued as rs759120376, COSV58620047, COSV58624686; called by muse, mutect2, varscan2
- FTMT | c.609G>T p.K203N | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV100360338; called by muse, mutect2, varscan2
- GAL3ST3 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.744); catalogued as COSV100360869; called by muse, mutect2, varscan2
- GALNT12 | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs748104709, COSV100899135; ClinVar: uncertain significance; called by muse, mutect2
- GCC1 | c.106A>C p.K36Q | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99133749; called by muse, mutect2, varscan2
- GDAP1 | c.311-1G>T p.X104_splice | Splice Site (SNP) | VAF 18/51 reads (35%) | catalogued as CS056089, COSV99619572; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.822G>T p.*274Yext*49 | Nonstop Mutation (SNP) | VAF 94/157 reads (60%) | catalogued as COSV100374476; called by muse, mutect2, varscan2
- GHSR | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.315); catalogued as COSV99576936; called by muse, mutect2, varscan2
- GPR157 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101072576; called by muse, mutect2
- GPR158 | c.840del p.W281Gfs*24 | Frame Shift Del (DEL) | VAF 13/36 reads (36%) | catalogued as COSV66277400; called by mutect2, pindel, varscan2
- GRM5 | c.1669T>C p.W557R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100551955; called by muse, mutect2, varscan2
- GRM5 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100551956, COSV59632113; called by muse, mutect2, varscan2
- HDC | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99984023; called by muse, mutect2, varscan2
- HEATR1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV63981073; called by muse, mutect2, varscan2
- HIP1R | c.1874G>C p.R625P | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.179); catalogued as COSV99458777; called by muse, mutect2, varscan2
- HTR1E | c.551T>C p.I184T | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100541105; called by muse, mutect2, varscan2
- HTR3B | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as COSV99491992; called by muse, mutect2, varscan2
- HTRA2 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99239674; called by muse, mutect2, varscan2
- IBA57 | c.587G>T p.W196L | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV100812775; called by muse, mutect2, varscan2
- IDH1 | c.905C>G p.T302R | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100576743; called by muse, mutect2, varscan2
- IFT74 | c.1109-1G>C p.X370_splice | Splice Site (SNP) | VAF 13/30 reads (43%) | catalogued as COSV101197176; called by muse, mutect2, varscan2
- IGF2R | c.4416C>G p.I1472M | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100807380; called by muse, mutect2, varscan2
- INSR | c.3325G>T p.G1109* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100252245; called by muse, mutect2
- INTS11 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs373444911; called by muse, mutect2
- ITGA5 | c.863A>T p.D288V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99516660; called by muse, mutect2, varscan2
- KAT6B | c.5164A>G p.T1722A | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV99768085; called by muse, mutect2, varscan2
- KCNK10 | c.1219C>A p.R407S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as COSV56648296; called by muse, varscan2
- KCNK10 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs145338578; called by muse, varscan2
- KCNK9 | c.802del p.R268Afs*75 | Frame Shift Del (DEL) | VAF 27/118 reads (23%) | catalogued as COSV57277776, COSV57281318; called by mutect2, pindel, varscan2
- KCNK9 | c.385G>T p.G129C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100271000; called by muse, mutect2
- KCNQ2 | c.1420G>T p.E474* (on ENST00000359125 / NM_172107.4; = p.E446* on NM_004518.6) | Nonsense Mutation (SNP) | VAF 56/137 reads (41%) | catalogued as COSV100610150, COSV60548479; called by muse, mutect2, varscan2
- KHSRP | c.762G>C p.E254D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs577750058, COSV101231188; called by muse, mutect2, varscan2
- KIAA1549L | c.732G>T p.L244F (on ENST00000321505; = p.L541F on NM_012194.3) | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.001); catalogued as COSV99683503; called by muse, mutect2, varscan2
- KIF1B | c.1861+1G>T p.X621_splice (on ENST00000377086 / NM_001365952.1; = p.X575_splice on NM_015074.3) | Splice Site (SNP) | VAF 24/44 reads (55%) | catalogued as COSV99823296; called by muse, mutect2, varscan2
- KIR2DL4 | c.209C>A p.P70H (on ENST00000396284; = p.P31H on NM_001080770.2) | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100610603; called by muse, mutect2, varscan2
- KLHL36 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99256791; called by muse, mutect2, varscan2
- KMT2D | c.11191G>T p.A3731S | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.444); catalogued as COSV99981822; called by muse, mutect2, varscan2
- KMT2D | c.6296G>T p.R2099L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99981827; called by muse, mutect2, varscan2
- KRTAP19-6 | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100473849; called by muse, mutect2, varscan2
- KRTCAP3 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1402645377, COSV99275023; called by muse, mutect2, varscan2
- LDLRAD1 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100997600; called by muse, mutect2, varscan2
- LRFN2 | c.260C>G p.T87S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV100599565; called by muse, mutect2, varscan2
- LRP8 | c.1072T>C p.F358L | Missense Mutation (SNP) | VAF 80/125 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as COSV100036478; called by muse, mutect2, varscan2
- LRRC31 | c.758C>T p.T253I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.282); catalogued as rs1198642222, COSV99246730; called by muse, mutect2, varscan2
- LRRIQ1 | c.1299G>T p.K433N | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV101280322; called by muse, mutect2, varscan2
- MAPK6 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs1383832953, COSV55929821; called by muse, mutect2, varscan2
- MEGF8 | c.6718T>C p.C2240R (on ENST00000251268 / NM_001271938.2; = p.C2173R on NM_001410.3) | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99236322; called by muse, mutect2, varscan2
- MID2 | c.1871C>T p.S624L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99464733; called by muse, mutect2, varscan2
- MLXIPL | c.2234A>T p.Q745L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100515340; called by muse, mutect2, varscan2
- MNAT1 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99710227; called by muse, mutect2, varscan2
- MSH4 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99591623; called by muse, mutect2, varscan2
- MTOR | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 108/180 reads (60%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100816186; called by muse, mutect2, varscan2
- MUC16 | c.5791del p.A1931Pfs*2 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as COSV101200617; called by mutect2, pindel, varscan2
- MUC17 | c.5665A>G p.T1889A | Missense Mutation (SNP) | VAF 193/500 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.095); catalogued as COSV100073264; called by muse, mutect2, varscan2
- MYBPH | c.1168G>T p.D390Y | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99704531; called by muse, mutect2
- MYBPH | c.430C>A p.R144S | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99703959; called by muse, mutect2, varscan2
- MYH2 | c.5336A>T p.Q1779L | Missense Mutation (SNP) | VAF 50/103 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99820136; called by muse, mutect2, varscan2
- MYH7 | c.4159G>T p.E1387* | Nonsense Mutation (SNP) | VAF 55/148 reads (37%) | catalogued as COSV100806114, COSV62515838; called by muse, mutect2, varscan2
- MYH7B | c.2050G>C p.E684Q | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV53422943; called by muse, mutect2, varscan2
- MYH7B | c.2175G>C p.E725D | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV99482788; called by muse, mutect2, varscan2
- MYO7B | c.5051G>T p.R1684L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as COSV101268181; called by muse, mutect2, varscan2
- NCR2 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100897224; called by muse, mutect2, varscan2
- NEB | c.7105G>A p.A2369T | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99423023; called by muse, mutect2, varscan2
- NEFH | c.1199C>G p.A400G | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV100151563; called by muse, mutect2, varscan2
- NEUROD6 | c.461A>G p.K154R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV99774047; called by muse, mutect2, varscan2
- NR1I2 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100561561; called by muse, varscan2
- NRCAM | c.2233G>A p.E745K (on ENST00000379028 / NM_001371124.1; = p.E729K on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61042571; called by muse, mutect2, varscan2
- NRG3 | c.1096T>C p.C366R | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100931419; called by muse, mutect2, varscan2
- NTNG1 | c.167A>T p.D56V | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99637430; called by muse, mutect2, varscan2
- NTSR2 | c.830A>G p.Q277R | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100183904; called by muse, mutect2, varscan2
- OR10S1 | c.899T>A p.F300Y | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV101602470; called by muse, mutect2, varscan2
- OR11A1 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs376499437; called by muse, mutect2, varscan2
- OR2C3 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as rs147306837, COSV63574800; called by muse, mutect2, varscan2
- OR2L2 | c.644G>T p.C215F | Missense Mutation (SNP) | VAF 92/175 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100823681; called by muse, mutect2, varscan2
- OR4A15 | c.176T>A p.F59Y | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.323); catalogued as COSV100124083; called by muse, mutect2, varscan2
- OR4B1 | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.055); catalogued as COSV100535607; called by muse, mutect2
- OR4C15 | c.630G>A p.M210I (on ENST00000314644; = p.M156I on NM_001001920.2) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1471878131, COSV100115359, COSV58952128; called by muse, mutect2, varscan2
- OR4K1 | c.79T>G p.F27V | Missense Mutation (SNP) | VAF 42/438 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV99578988; called by muse, mutect2
- OR5K1 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV60304432; called by muse, mutect2, varscan2
- OR6C75 | c.58C>T p.Q20* | Nonsense Mutation (SNP) | VAF 71/175 reads (41%) | catalogued as COSV100595338; called by muse, mutect2, varscan2
- OSCP1 | c.956G>T p.R319L (on ENST00000356637 / NM_001330493.1; = p.R309L on NM_145047.5) | Missense Mutation (SNP) | VAF 95/340 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99347296; called by muse, mutect2, varscan2
- OTOL1 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100019988, COSV60006561; called by muse, mutect2, varscan2
- PAIP1 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100166605; called by muse, mutect2, varscan2
- PANK1 | c.78A>T p.E26D | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.076); catalogued as COSV100285652; called by muse, varscan2
- PAPPA | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100074073, COSV60286876; called by muse, mutect2, varscan2
- PARPBP | c.654G>T p.M218I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV100569188; called by muse, mutect2, varscan2
- PAX7 | c.1176C>A p.N392K | Missense Mutation (SNP) | VAF 66/129 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.185); catalogued as COSV100946789; called by muse, mutect2, varscan2
- PAX7 | c.1177C>A p.P393T | Missense Mutation (SNP) | VAF 67/131 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as COSV100946790; called by muse, mutect2, varscan2
- PCDH11Y | c.351C>G p.F117L (on ENST00000400457 / NM_032973.2; = p.F106L on NM_032971.3) | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV99291497; called by muse, mutect2, varscan2
- PCDHA6 | c.1973C>T p.A658V | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.036); catalogued as rs148379064, COSV65347147; called by muse, mutect2, varscan2
- PCDHGB2 | c.1706C>T p.P569L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99538399; called by muse, mutect2, varscan2
- PCLO | c.864A>G p.I288M | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.103); catalogued as COSV100432702; called by muse, mutect2, varscan2
- PEX6 | c.2785A>T p.R929W | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99769765; called by muse, mutect2, varscan2
- PFAS | c.1282G>A p.G428R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100118925; called by muse, mutect2, varscan2
- PHC1 | c.104A>T p.Q35L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101418606; called by muse, mutect2, varscan2
- PIGR | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.68); PolyPhen benign (0.023); catalogued as COSV100732513, COSV62903373; called by muse, mutect2, varscan2
- PIGZ | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV53014169; called by muse, mutect2, varscan2
- PKD1 | c.7531G>T p.A2511S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0.031); catalogued as COSV99238139; called by muse, mutect2, varscan2
- PKHD1 | c.5552A>T p.D1851V | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV100583096, COSV100583617; called by muse, mutect2, varscan2
- PKHD1L1 | c.11785C>A p.P3929T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV101006144; called by muse, mutect2, varscan2
- PKP2 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV50731465, COSV99297728; called by muse, mutect2, varscan2
- PLA2G6 | c.2030G>T p.R677L | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.343); catalogued as rs369038599, CM166192, COSV99061469; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCD1 | c.1612G>A p.G538S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs141516535; called by muse, mutect2, varscan2
- PLCG2 | c.3418G>A p.D1140N | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63867491; called by muse, mutect2, varscan2
- PLCL1 | c.1865G>A p.R622H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368662764, COSV70820887; called by mutect2, varscan2
- PLCXD1 | c.549G>T p.G183= | Splice Region (SNP) | VAF 32/146 reads (22%) | catalogued as COSV101087879; called by muse, mutect2, varscan2
- PLSCR5 | c.512C>G p.P171R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs770708329, COSV101494491; called by muse, varscan2
- PLXNB2 | c.976A>T p.N326Y | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV100834060; called by muse, mutect2, varscan2
- PODNL1 | c.764T>C p.F255S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99582877; called by muse, varscan2
- POM121L12 | c.167G>T p.R56M | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.227); catalogued as COSV68693556; called by muse, mutect2
- POU2F3 | c.1087C>G p.L363V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as COSV52795445; called by muse, mutect2, varscan2
- PRG2 | c.68C>A p.T23N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV100314919; called by muse, mutect2
- PRRT2 | c.912C>A p.D304E | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV54882291, COSV99569199; called by muse, mutect2, varscan2
- PTPRC | c.2240T>G p.V747G | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100722659, COSV61411278; called by muse, mutect2, varscan2
- PTPRK | c.4040C>T p.S1347F (on ENST00000368215 / NM_001291984.2; = p.S1348F on NM_002844.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63902028; called by muse, mutect2, varscan2
- PUS1 | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100435212; called by muse, mutect2, varscan2
- PZP | c.460T>G p.F154V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99737844; called by muse, mutect2, varscan2
- RABL3 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV99846504; called by muse, mutect2, varscan2
- RAPGEF5 | c.1610G>A p.C537Y (on ENST00000401957 / NM_001367602.2; = p.C840Y on NM_012294.5) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV59779693; called by muse, mutect2, varscan2
- RB1CC1 | c.1915C>A p.Q639K | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.175); catalogued as COSV99212256; called by muse, mutect2
- RBBP6 | c.952-1G>T p.X318_splice | Splice Site (SNP) | VAF 12/49 reads (24%) | catalogued as COSV60508640; called by muse, mutect2, varscan2
- RBBP6 | c.952G>T p.A318S | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100154598; called by muse, mutect2, varscan2
- REC114 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV100461389; called by muse, mutect2, varscan2
- RFX4 | c.1912C>A p.P638T (on ENST00000392842 / NM_213594.3; = p.P544T on NM_032491.6) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99985858; called by muse, mutect2, varscan2
- RHBDF2 | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as COSV100489398; called by muse, mutect2, varscan2
- RNF166 | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); catalogued as COSV100455496; called by muse, mutect2
- RNF8 | c.1129G>C p.E377Q | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV100009573; called by muse, mutect2
- RTL3 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 38/58 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV100329782, COSV58183264; called by muse, mutect2, varscan2
- RTL3 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs747360888, COSV100329783; called by muse, mutect2, varscan2
- RYR1 | c.7052A>G p.N2351S | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as rs779349184, COSV100615736; called by muse, mutect2, varscan2
- RYR3 | c.2960C>A p.A987E | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101212776; called by muse, mutect2, varscan2
- SALL1 | c.2761G>T p.E921* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99173927; called by muse, mutect2, varscan2
- SCN2A | c.5627G>A p.R1876Q | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1197385793, COSV51833190; called by muse, mutect2, varscan2
- SHPRH | c.3865_3866insT p.R1289Lfs*8 (on ENST00000275233 / NM_001042683.3; = p.R1293Lfs*8 on NM_173082.3) | Frame Shift Ins (INS) | VAF 9/57 reads (16%) | catalogued as COSV99262072; called by mutect2, varscan2
- SLC22A2 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs1366541162, COSV100870986; called by muse, mutect2, varscan2
- SLC30A10 | c.1039G>T p.A347S | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100751510; called by muse, mutect2, varscan2
- SLIT1 | c.4112T>G p.L1371R | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV99821390; called by muse, mutect2, varscan2
- SOAT2 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs771080176, COSV100037481; called by muse, mutect2, varscan2
- SP8 | c.1249G>A p.A417T (on ENST00000361443 / NM_198956.4; = p.A435T on NM_182700.6) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV100815353; called by muse, mutect2
- SPATC1L | c.880A>C p.N294H (on ENST00000291672 / NM_001142854.2; = p.N140H on NM_032261.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99385977; called by muse, varscan2
- ST6GALNAC3 | c.541C>A p.P181T | Missense Mutation (SNP) | VAF 46/73 reads (63%) | PolyPhen probably damaging (0.991); catalogued as COSV100083243, COSV60348286; called by muse, mutect2, varscan2
- STXBP6 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 67/137 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.043); catalogued as rs752590093, COSV60590522; called by muse, mutect2, varscan2
- SULT1B1 | c.667A>T p.R223W | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100150267, COSV60207935; called by muse, mutect2, varscan2
- SUN5 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 30/223 reads (13%) | catalogued as COSV100644829; called by muse, mutect2, varscan2
- SUN5 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 36/386 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV62183322; called by muse, mutect2
- TBCCD1 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | catalogued as COSV100111975; called by muse, mutect2
- TDP2 | c.357G>T p.W119C | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100593667; called by muse, mutect2, varscan2
- TFDP3 | c.1111G>A p.G371S | Missense Mutation (SNP) | VAF 97/134 reads (72%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs372309436, COSV100033386; called by muse, mutect2, varscan2
- THBS2 | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.001); catalogued as COSV100827892; called by muse, mutect2, varscan2
- THSD7B | c.4326G>A p.W1442* (on ENST00000272643; = p.W1440* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as COSV99750896; called by muse, mutect2, varscan2
- TIAM1 | c.1088G>T p.R363L | Missense Mutation (SNP) | VAF 93/231 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.2); catalogued as COSV99735115; called by muse, mutect2, varscan2
- TLK1 | c.993G>T p.W331C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100688272; called by muse, mutect2, varscan2
- TMEM132D | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.958); catalogued as COSV101397858; called by muse, mutect2, varscan2
- TMEM39A | c.1016C>T p.P339L | Missense Mutation (SNP) | VAF 98/252 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052407; called by muse, mutect2, varscan2
- TMEM63B | c.2220C>G p.N740K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.451); catalogued as COSV99441519; called by muse, mutect2, varscan2
- TP53 | c.514del p.V172Lfs*2 | Frame Shift Del (DEL) | VAF 23/54 reads (43%) | catalogued as CM115637, COSV52672812, COSV52700410; called by mutect2, pindel, varscan2
- TP53TG5 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.286); catalogued as rs116218782; called by muse, mutect2, varscan2
- TPCN1 | c.1403G>T p.G468V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV100136701; called by muse, mutect2, varscan2
- TPH2 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 85/396 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1386735125, COSV61593711; called by muse, mutect2, varscan2
- TRHDE | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as COSV99670831; called by muse, mutect2, varscan2
- TRHDE | c.1940T>A p.V647E | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV99670833, COSV99671913; called by muse, mutect2
- TRIM17 | c.1058G>A p.W353* | Nonsense Mutation (SNP) | VAF 15/109 reads (14%) | catalogued as rs1458879015, COSV99488410, COSV99488915; called by muse, mutect2, varscan2
- TRPC3 | c.2057C>A p.T686N (on ENST00000379645 / NM_001366479.2; = p.T613N on NM_003305.2) | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV53371922, COSV53378149; called by muse, mutect2, varscan2
- TRPC4AP | c.1230G>C p.M410I | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.069); catalogued as COSV99328381; called by muse, mutect2, varscan2
- TSC1 | c.2465_2466del p.C822Sfs*3 | Frame Shift Del (DEL) | VAF 85/216 reads (39%) | catalogued as rs118203694; called by pindel, varscan2
- URI1 | c.304del p.D102Tfs*13 | Frame Shift Del (DEL) | VAF 37/129 reads (29%) | catalogued as rs754569782; called by mutect2, pindel, varscan2
- USH2A | c.9578G>C p.C3193S | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100234717; called by muse, mutect2
- USP13 | c.1798+1G>A p.X600_splice | Splice Site (SNP) | VAF 36/79 reads (46%) | catalogued as COSV99831163; called by muse, mutect2, varscan2
- USP24 | c.6955G>T p.A2319S | Missense Mutation (SNP) | VAF 39/54 reads (72%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99599735; called by muse, mutect2, varscan2
- USP6NL | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV104375015, COSV99509646; called by muse, mutect2, varscan2
- USP8 | c.137C>A p.T46K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100209002; called by muse, mutect2, varscan2
- VAV3 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100894439; called by muse, mutect2, varscan2
- VN1R4 | c.535C>A p.L179M | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); catalogued as COSV100237421; called by muse, mutect2, varscan2
- VNN1 | c.1153G>T p.G385* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as rs755344903, COSV100907719, COSV63390840, COSV63391001; called by muse, mutect2, varscan2
- VPS13B | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100662009; called by muse, mutect2, varscan2
- VPS13B | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100662013; called by muse, mutect2
- WDR26 | c.2120C>T p.A707V (on ENST00000414423 / NM_001379403.1; = p.A607V on NM_025160.7) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs765333763, COSV54360248; called by muse, mutect2, varscan2
- WSCD2 | c.1526G>T p.C509F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99774649; called by muse, mutect2, varscan2
- WWP2 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs755244675, COSV100598556; called by muse, mutect2
- YWHAZ | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100782545; called by muse, mutect2, varscan2
- ZBP1 | c.1186C>A p.L396M | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.36); catalogued as COSV100473480; called by muse, mutect2, varscan2
- ZCCHC4 | c.1438A>T p.N480Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV100255250; called by muse, mutect2, varscan2
- ZFP2 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.904); catalogued as rs1429275307, COSV100797057; called by muse, mutect2, varscan2
- ZNF382 | c.1435C>A p.L479I | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV99497804; called by muse, mutect2, varscan2
- ZNF407 | c.2647G>T p.V883L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.402); catalogued as COSV55276062; called by muse, mutect2, varscan2
- ZNF585B | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.207); catalogued as COSV100459452, COSV57216969; called by muse, mutect2, varscan2
- ZNF610 | c.320-2A>G p.X107_splice | Splice Site (SNP) | VAF 45/144 reads (31%) | catalogued as COSV100016847, COSV58345739; called by muse, mutect2, varscan2
- ZNF671 | c.131C>A p.S44Y | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV100235042; called by muse, mutect2, varscan2
- ZNF708 | c.929G>A p.C310Y | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100803101; called by muse, mutect2, varscan2
- ZNF804A | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV56444738, COSV56447834; called by muse, mutect2, varscan2
- ZNF808 | c.809A>C p.H270P | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); catalogued as COSV100707939; called by muse, mutect2
- ZNF830 | c.200A>C p.Q67P | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs377669068, COSV100030671; called by muse, mutect2, varscan2
- ZNF91 | c.1734A>C p.E578D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV100322715; called by muse, mutect2, varscan2
- ZNF99 | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV68055331; called by muse, mutect2, varscan2
- ASAH2 | c.1649G>C p.R550P | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ASAH2 | c.953A>C p.N318T | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CLN6 | c.430del p.H144Tfs*19 | Frame Shift Del (DEL) | VAF 40/210 reads (19%) | called by mutect2, pindel, varscan2
- FOXG1 | c.1291del p.S431Afs*4 | Frame Shift Del (DEL) | VAF 26/71 reads (37%) | called by mutect2, pindel, varscan2
- HELB | c.2711dup p.R906Pfs*38 | Frame Shift Ins (INS) | VAF 33/138 reads (24%) | called by mutect2, pindel, varscan2
- IFI27L2 | c.102del p.A35Rfs*4 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- IGHV7-81 | c.9G>C p.W3C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV1-17 | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 148/366 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.165); called by muse, varscan2
- IGKV1D-17 | c.48G>C p.W16C | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- IGKV2D-30 | c.285T>A p.D95E | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- INPP4B | c.1224del p.A410Qfs*15 | Frame Shift Del (DEL) | VAF 37/145 reads (26%) | called by mutect2, pindel, varscan2
- NEU1 | c.253A>G p.T85A | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2
- OR2AK2 | c.443del p.A148Dfs*54 | Frame Shift Del (DEL) | VAF 81/200 reads (41%) | called by mutect2, pindel, varscan2
- OSBPL6 | c.354_360del p.Y118* | Frame Shift Del (DEL) | VAF 19/138 reads (14%) | called by mutect2, pindel, varscan2
- PDE10A | c.1277_1278+10del p.X426_splice | Splice Site (DEL) | VAF 10/60 reads (17%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.246del p.T83Rfs*26 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | called by mutect2, pindel, varscan2
- PPP1R12C | c.1648del p.S550Pfs*14 | Frame Shift Del (DEL) | VAF 20/157 reads (13%) | called by mutect2, pindel, varscan2
- REPS2 | c.928_930del p.F310del | In Frame Del (DEL) | VAF 22/93 reads (24%) | called by pindel, varscan2
- ROS1 | c.4246del p.A1416Pfs*6 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- SLC30A3 | c.892del p.R298Afs*167 | Frame Shift Del (DEL) | VAF 38/103 reads (37%) | called by mutect2, pindel, varscan2
- SMPD3 | c.214del p.V72Wfs*232 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- UNC45A | c.1263_1264del p.L422Afs*5 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- VIPAS39 | c.925del p.H309Ifs*2 | Frame Shift Del (DEL) | VAF 43/120 reads (36%) | called by mutect2, pindel, varscan2
- ZFP64 | c.674_677del p.H225Rfs*49 | Frame Shift Del (DEL) | VAF 27/260 reads (10%) | called by mutect2, pindel, varscan2
- ZNF264 | c.1457_1458insACGT p.E487Rfs*21 | Frame Shift Ins (INS) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- ABCB4 | c.552C>A p.I184= | Silent (SNP) | VAF 43/130 reads (33%) | catalogued as COSV99710449; called by muse, mutect2, varscan2
- ABCC4 | c.3267T>C p.F1089= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100972508; called by muse, mutect2, varscan2
- ABCG8 | c.1524C>A p.I508= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV55392369, COSV99699800; called by muse, mutect2, varscan2
- ACSM5 | c.813T>A p.T271= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs200782835; called by muse, mutect2, varscan2
- ANK1 | c.1890C>T p.A630= | Silent (SNP) | VAF 53/500 reads (11%) | catalogued as rs143600719; called by muse, mutect2, varscan2
- APOBR | c.1086G>A p.E362= (on ENST00000431282; = p.E371= on NM_018690.4) | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV100112573; called by muse, mutect2, varscan2
- B4GAT1 | c.1098G>C p.L366= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV100240262; called by muse, mutect2, varscan2
- BRINP3 | c.1434C>T p.V478= | Silent (SNP) | VAF 18/192 reads (9%) | catalogued as COSV66536903; called by muse, mutect2
- CACNA1G | c.879C>T p.G293= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1356133711, COSV61736946; called by muse, mutect2, varscan2
- CADM3 | c.852G>T p.L284= (on ENST00000368125 / NM_001127173.3; = p.L318= on NM_021189.5) | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV100930339, COSV63687342; called by muse, mutect2, varscan2
- CARD18 | c.48A>G p.S16= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs1282566332, COSV73233147; called by muse, mutect2, varscan2
- CCDC172 | c.630T>A p.P210= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV100319798; called by muse, mutect2, varscan2
- CDH10 | c.744C>A p.G248= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV100051466, COSV100053232; called by muse, mutect2, varscan2
- CDIPT | c.273G>A p.T91= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs748598961, COSV99570195; called by muse, mutect2, varscan2
- CFAP45 | c.1443G>A p.Q481= | Silent (SNP) | VAF 19/121 reads (16%) | catalogued as COSV100928584; called by muse, mutect2, varscan2
- CLNK | c.930C>T p.Y310= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs769252961, COSV99905177; called by muse, varscan2
- CNTNAP2 | c.3909G>T p.S1303= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV100666613; called by muse, mutect2, varscan2
- COL6A3 | c.9072C>A p.V3024= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs1480447833, COSV99798319; called by muse, mutect2, varscan2
- CORIN | c.2244G>A p.P748= | Silent (SNP) | VAF 32/133 reads (24%) | catalogued as rs150493343; called by muse, mutect2, varscan2
- DEFB129 | c.414C>A p.I138= | Silent (SNP) | VAF 84/143 reads (59%) | catalogued as COSV99857455; called by muse, mutect2, varscan2
- DHX57 | c.2043G>T p.L681= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99769538; called by muse, mutect2, varscan2
- DMGDH | c.2487G>C p.V829= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV99668997; called by muse, mutect2, varscan2
- DNAAF6 | c.576C>A p.I192= | Silent (SNP) | VAF 74/101 reads (73%) | catalogued as COSV100314513; called by muse, mutect2, varscan2
- DPP6 | c.1131G>C p.R377= (on ENST00000377770 / NM_001364500.2; = p.R315= on NM_001936.5) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100125592; called by muse, mutect2
- DSCAM | c.5787G>A p.L1929= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV68031120; called by muse, mutect2, varscan2
- FAM155A | c.156C>G p.L52= | Silent (SNP) | VAF 37/98 reads (38%) | catalogued as COSV101028005; called by muse, mutect2, varscan2
- FBXO40 | c.1782C>A p.A594= | Silent (SNP) | VAF 33/66 reads (50%) | catalogued as COSV100573169; called by muse, mutect2, varscan2
- FNBP4 | c.1875G>A p.E625= | Silent (SNP) | VAF 41/142 reads (29%) | catalogued as COSV99771668; called by muse, mutect2, varscan2
- GABBR1 | c.2802C>T p.P934= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100589706; called by muse, mutect2
- GATA4 | c.754C>A p.R252= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as CM131318, COSV100632871; called by muse, mutect2, varscan2
- GBP3 | c.1668C>A p.A556= | Silent (SNP) | VAF 40/63 reads (63%) | catalogued as COSV99352514; called by muse, mutect2, varscan2
- GDF5 | c.483G>A p.P161= | Silent (SNP) | VAF 25/260 reads (10%) | catalogued as rs752789551, COSV65501445; ClinVar: uncertain significance; called by muse, mutect2
- GPM6A | c.156T>A p.S52= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as COSV99704001; called by muse, mutect2, varscan2
- IL17A | c.180C>T p.P60= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV100391528, COSV60683795, COSV60685238; called by muse, mutect2, varscan2
- KCNK9 | c.387C>T p.G129= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV57279035; called by muse, mutect2
- KIAA2026 | c.6276G>T p.S2092= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs549927214, COSV101199052; called by muse, varscan2
- KIF2B | c.661C>A p.R221= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV52126920, COSV52127326; called by muse, mutect2, varscan2
- LRBA | c.5988G>T p.V1996= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100840743, COSV100841548; called by muse, mutect2, varscan2
- MMP19 | c.234C>A p.A78= | Silent (SNP) | VAF 41/112 reads (37%) | catalogued as COSV100491106; called by muse, mutect2, varscan2
- MUC20 | c.1893A>T p.S631= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as rs546246793, COSV100291175; called by muse, mutect2, varscan2
- MYF6 | c.684G>T p.S228= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV99952813; called by muse, mutect2, varscan2
- MYH7B | c.2253G>A p.R751= | Silent (SNP) | VAF 21/177 reads (12%) | catalogued as rs377707540; called by muse, mutect2, varscan2
- MYO7B | c.3594C>A p.P1198= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV101268180; called by muse, mutect2
- MYPN | c.951C>A p.I317= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as rs759998419, COSV100589976; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- NID2 | c.564T>A p.S188= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99356547; called by muse, mutect2, varscan2
- OR4C3 | c.750G>C p.V250= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV100167846; called by muse, mutect2, varscan2
- OR4K14 | c.141C>A p.V47= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV100520426; called by muse, mutect2, varscan2
- OR7D4 | c.792G>T p.V264= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100432732; called by muse, mutect2, varscan2
- OR9G1 | c.204G>T p.L68= | Silent (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- ORM1 | c.360G>T p.L120= | Silent (SNP) | VAF 42/76 reads (55%) | catalogued as COSV52280203; called by muse, mutect2, varscan2
- PAAF1 | c.981C>G p.S327= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100142480; called by muse, mutect2, varscan2
- PAXIP1 | c.2475G>A p.L825= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV101249696; called by muse, mutect2, varscan2
- PIK3AP1 | c.228G>T p.V76= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100225772; called by muse, mutect2, varscan2
- PIK3CB | c.1107A>T p.V369= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV100005654; called by muse, mutect2, varscan2
- PRAMEF10 | c.1302G>T p.R434= | Silent (SNP) | VAF 52/135 reads (39%) | catalogued as COSV99338962; called by muse, mutect2, varscan2
- PSD4 | c.1503T>C p.S501= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as rs1422714457, COSV99831122; called by muse, mutect2, varscan2
- QRFPR | c.195G>T p.L65= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV100543727; called by muse, varscan2
- RAI14 | c.1359A>G p.K453= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV99463127; called by muse, mutect2, varscan2
- RBM10 | c.255G>T p.R85= | Silent (SNP) | VAF 108/122 reads (89%) | catalogued as COSV100237799; called by muse, mutect2, varscan2
- RHBDF2 | c.1170G>T p.V390= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV100489399; called by muse, mutect2, varscan2
- SCN5A | c.1581G>T p.G527= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100348379; called by muse, mutect2, varscan2
- SLC12A3 | c.2529C>G p.T843= (on ENST00000563236 / NM_001126108.2; = p.T852= on NM_000339.3) | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1211212808, COSV99344246; called by muse, mutect2, varscan2
- SLC2A8 | c.495C>T p.V165= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs148614863; called by muse, mutect2, varscan2
- SLC6A13 | c.624G>A p.L208= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as rs780279869, COSV100569936; called by muse, mutect2, varscan2
- SORCS1 | c.2409C>A p.V803= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV53883682, COSV99546435; called by muse, mutect2, varscan2
- SOX6 | c.1512G>A p.R504= (on ENST00000528429 / NM_001145819.2; = p.R477= on NM_017508.3) | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as rs1431841522, COSV100322205; called by muse, mutect2, varscan2
- TAS2R13 | c.570A>G p.P190= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as COSV101183741; called by muse, mutect2, varscan2
- TBC1D17 | c.712C>T p.L238= | Silent (SNP) | VAF 68/201 reads (34%) | catalogued as COSV99680647; called by muse, mutect2, varscan2
- TCF20 | c.5082G>T p.V1694= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV100166573, COSV59497687; called by muse, mutect2, varscan2
- THRA | c.894C>T p.A298= | Silent (SNP) | VAF 77/145 reads (53%) | catalogued as COSV99225504; called by muse, mutect2, varscan2
- TMEM132D | c.2295C>G p.T765= | Silent (SNP) | VAF 22/99 reads (22%) | catalogued as rs776511959, COSV101242837, COSV67161742; called by muse, mutect2, varscan2
- TSHZ2 | c.108C>T p.S36= | Silent (SNP) | VAF 26/59 reads (44%) | catalogued as rs752591081, COSV61591078; called by muse, mutect2, varscan2
- TTN | c.26580G>A p.E8860= (on ENST00000591111; = p.E7933= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs1339109006, COSV100612827; called by muse, mutect2, varscan2
- TTN | c.11514A>G p.V3838= (on ENST00000591111; = p.V3792= on NM_003319.4) | Silent (SNP) | VAF 38/121 reads (31%) | catalogued as COSV100612828; called by muse, mutect2, varscan2
- USH2A | c.9075T>A p.P3025= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as COSV100234721; called by muse, mutect2, varscan2
- VWF | c.4855C>T p.L1619= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2
- WASL | c.159G>T p.R53= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV99771661; called by muse, mutect2, varscan2
- ZNF649 | c.99C>T p.Y33= | Silent (SNP) | VAF 82/259 reads (32%) | catalogued as COSV100725426; called by muse, mutect2, varscan2
- CARMIL3 | chr14:24050920 C>A | 5'Flank (SNP) | VAF 17/69 reads (25%) | called by muse, mutect2, varscan2
- DCX | c.-22-540C>A | Intron (SNP) | VAF 82/107 reads (77%) | catalogued as COSV100576442; called by muse, mutect2, varscan2
- GET1-SH3BGR | c.*1G>T | 3'UTR (SNP) | VAF 89/151 reads (59%) | catalogued as COSV100374477; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22331C>A | Intron (SNP) | VAF 18/60 reads (30%) | catalogued as rs965913342, COSV101051131; called by muse, mutect2, varscan2
- MASP1 | c.1303+5672_1303+5673dup | Intron (INS) | VAF 18/57 reads (32%) | called by mutect2, varscan2
- TMEM236 | c.*2166G>T | 3'UTR (SNP) | VAF 23/58 reads (40%) | catalogued as COSV100592567; called by muse, mutect2, varscan2
- TTN | c.10360+4906A>G | Intron (SNP) | VAF 10/41 reads (24%) | catalogued as rs549404410, COSV100612830; called by muse, mutect2, varscan2
- USH1C | c.1284+7589G>A | Intron (SNP) | VAF 34/55 reads (62%) | catalogued as rs1345367368, COSV99140044; called by muse, mutect2, varscan2
